Gene-level copy-number profile of tumor specimen TCGA-LN-A8HZ-01A from TCGA case TCGA-LN-A8HZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 56.2 years (20,510 days).
Specimen TCGA-LN-A8HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d67bbfe3-d776-4b7d-9421-501df32b9073.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A8HZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e4db51a-7a06-4342-bb36-f94ed74d353b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,491; copy number 3: 9,201; copy number 4: 21,725; copy number 5: 13,569; copy number 6: 2,601; copy number 7: 1,594; copy number 8: 914; copy number 9: 709.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A8HZ-01A-11D-A36I-01): tumor purity 0.72, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 709 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:138,470,656–138,975,006, 10 genes, copy number 9: AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1.
- chr3:166,293,756–198,222,513, 623 genes, copy number 9 (broad region; genes not listed).
- chr20:34,833,575–36,870,402, 76 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
